Gene-level copy-number profile of specimen HCM-SANG-0308-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-0308-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0308-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5070a6cc-4b9b-4c93-b6e0-6bf42e6faaa4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0308-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,735 have no estimate.
https://portal.gdc.cancer.gov/files/e275ca49-6998-4776-b31c-e3861ec72ac3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 654; copy number 1: 9; copy number 2: 3,661; copy number 3: 19,396; copy number 4: 19,479; copy number 5: 11,795; copy number 6: 1,399; copy number 7: 2,217; copy number 8: 13; copy number 9: 181; copy number 10: 31; copy number 11: 4; copy number 22: 28; copy number 23: 7; copy number 30: 2; copy number 31: 3; copy number 34: 9.

Homozygous deletions (total copy number 0; autosomes only): 109 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,272,309–11,557,665, 4 genes (within-gene range 0–3): ATG7, AC083855.1, AC026185.1, AC022001.1.
- chr3:59,747,277–61,251,459, 8 genes: FHIT, AC093418.1, AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71, U3.
- chr4:49,502,145–49,508,806, 2 genes: ANKRD20A17P, AC119751.5.
- chr4:49,548,564–49,562,149, 5 genes: AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24.
- chr5:59,703,606–59,703,703, 1 gene (within-gene range 0–3): MIR582.
- chr18:5,721,812–9,020,764, 54 genes: MIR3976HG, MIR3976, TMEM200C, AP001021.1, AP001021.3, L3MBTL4, AP001021.2, RNU5F-3P, L3MBTL4-AS1, MIR4317, AP005060.1, RNU6-349P, RPL6P27, AP005202.2, LINC01387, AP005202.1, RN7SL282P, AP005205.1, AP005205.3, AP005205.2, ARHGAP28, AP005210.2, AP005210.1, LINC00668, SCML2P1, RNU6-916P, LAMA1, AP002409.1, AP005062.1, SLC25A51P2, LRRC30, AP005270.1, PTPRM, AP000897.2, AP000897.1, U3, AP005900.1, AC006566.2, AC006566.1, AP001094.3, AP001094.2, AP001094.1, COP1P1, RN7SL50P, THEMIS3P, AKR1B1P6, RAB12, AP001793.1, TOMM20P3, GACAT2, MTCL1, Y_RNA, AP000864.1, RPS4XP19.
- chr18:15,056,845–15,330,282, 8 genes: AP005242.3, AP005242.1, AP005901.2, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.
- chr18:50,879,080–51,688,209, 13 genes: ME2, Y_RNA, ELAC1, AC091551.1, SMAD4, SRSF10P1, MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1.
- chr18:64,677,796–66,604,138, 10 genes: AC027506.1, AC007948.1, AC007631.1, LINC01916, AC090358.1, CDH7, AC023394.2, AC023394.1, PRPF19P1, CDH19.
- chr18:68,721,082–68,721,560, 1 gene (within-gene range 0–4): AC040896.1.
- chr20:14,933,843–15,022,958, 3 genes (within-gene range 0–7): AL138808.1, RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 265 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:26,634,383–27,864,401, 49 genes, copy number 22–34 (within-gene range 3–34): ZNF322, AL513548.1, GUSBP2, POM121L6P, LINC00240, AL133255.1, AL590062.1, VN1R12P, VN1R13P, VN1R11P, RNU2-62P, AL021807.1, H2BC11, H2AC11, H4C9, H2BC12, H2AC12, MIR3143, RPL10P2, PRSS16, AL021808.1, POM121L2, VN1R10P, ZNF204P, ZNF391, AL031118.1, MCFD2P1, ZNF184, AL021918.4, AL021918.3, AL021918.2, AL021918.1, HNRNPA1P1, CD83P1, RNU6-471P, RPL8P1, LINC01012, GPR89P, RSL24D1P1, H4C10P, H2BC13, H2AC13, H3C10, H2AC14, H2BC14, H4C11, H4C12, H2AC15, H2BC16P.
- chr6:27,890,315–28,897,322, 57 genes, copy number 9–10: H3C12, H2AC17, H2BC17, RNU7-26P, OR2B2, OR2W6P, OR2B6, RPLP2P1, OR2W4P, IQCB2P, ZSCAN16-AS1, U3, OR2W2P, OR2B7P, OR2B8P, OR1F12, AL121944.1, ZNF165, ZSCAN12P1, ZNF602P, ZSCAN16, AL358933.1, ZKSCAN8, ZNF192P1, AL022393.1, ZNF603P, ZNF192P2, TOB2P1, ZSCAN9, ZKSCAN4, NKAPL, ZSCAN26, AL021997.2, PGBD1, AL021997.1, SMIM15P2, ZSCAN31, ZKSCAN3, ZSCAN12, RNU2-45P, ZSCAN23, COX11P1, OR2E1P, GPX6, GPX5, ZBED9, AL049543.1, AL121932.1, AL121932.2, LINC00533, RPSAP2, NOP56P1, AL662890.1, LINC01623, RPL13P, ZNF90P2, HCG14.
- chr6:28,943,877–30,962,396, 159 genes, copy number 9–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 9. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
